Surgical pathology report (de-identified scan), TCGA case TCGA-09-2045, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2045-01A (Primary Tumor).

[page 1 of 4]
FINAL PATHOLOGIC DIAGNOSIS

A. OMENTUM, OMENTECTOMY: METASTATIC HIGH-GRADE ADENOCARCINOMA WITH FEATURES OF OVARIAN PAPILLARY SEROUS CARCINOMA. SEE NOTE.

B. LEFT PELVIS, TUMOR MASS, BIOPSY: HIGH-GRADE ADENOCARCINOMA. SEE NOTE.

C. RIGHT OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY: PAPILLARY SEROUS ADENOCARCINOMA WITH INVASION INTO FALLOPIAN TUBE. SEE NOTE.

D. LEFT PELVIS, TUMOR MASS, BIOPSY: HIGH-GRADE ADENOCARCINOMA. SEE NOTE.

E. PELVIS, TUMOR MASS, BIOPSY: HIGH-GRADE ADENOCARCINOMA, PREDOMINANTLY SEROUS PAPILLARY. SEE NOTE.

F. SIGMOID, TUMOR MASS, BIOPSY: HIGH-GRADE ADENOCARCINOMA. SEE NOTE.

G. UTERUS AND CERVIX, ABDOMINAL HYSTERECTOMY: UTERUS:

1. POSTERIOR SEROSAL IMPLANT OF SEROUS PAPILLARY ADENOCARCINOMA. SEE NOTE.

2. LEFT PARAMETRIAL TISSUE WITH SEROUS PAPILLARY ADENOCARCINOMA INVOLVEMENT.

3. INACTIVE ENDOMETRIUM.

Page 1 of 4

CERVIX:

1. SQUAMOUS METAPLASIA.

H. SIGMOID SEROSA, TUMOR MASS, BIOPSY: HIGH-GRADE ADENOCARCINOMA. SEE NOTE.

COMMENT:

NOTES:

This high-grade adenocarcinoma appears to be of ovarian origin with widespread peritoneal implants. The carcinoma shows a predominantly serous papillary pattern, but a large amount of the tumor burden displays a solid glandular pattern. Numerous psammoma bodies are present. Focal lymphovascular invasion is seen.

Although no peritoneal wash specimen was obtained, peritoneal washings are presumed to be positive due to the large amount of tumor present in the peritoneal cavity as well as tumor invasion present in the fallopian tube.

Given the pelvic extension, uterine implant and presumed positive peritoneal wash, the pathologic stage of this tumor according to the UICC system would be pT2cNXMX.

Specimen(s) Received

A:A) OMENTUM

B:B) PELVIC MASS LEFT

C:C) RT OVARY & TUBE

:D) LT PELVIC MASS

:E) PELVIC TUMOR

[page 2 of 4]
[REDACTED]
F:F) UTERUS & CERVIX
G:G) SIGMOID TUMOR
H:H) SIGMOID SEROSA TUMOR

Clinical History

[REDACTED] with ovarian carcinoma.

Gross Description

The specimen is received in multiple parts labeled with the patient's name and ID number. Parts A through E are received fresh and parts F through H are received in formalin.

Parts A, additionally labeled "omentum" consists of a large mass of soft, irregularly-shaped, red-white-yellow tissue measuring 15.0 x 12.0 x 6.0 cm in greatest dimension. This tissue mass appears to comprise of some omental fat which is studded with multiple nodules of varying sizes. The nodules appear to be confluent in some areas. The nodules range in size from 0.3 x 0.3 x 0.2 cm to 6.0 x 5.0 x 3.0 cm. These multiple nodules appear to have various consistencies. One of the large nodules is tan-white and firm; a section of this large firm nodule is submitted for frozen section.

FROZEN SECTION DIAGNOSIS #1

Omentum, biopsy: tissue consistent with metastatic carcinoma of ovarian origin, with features of
Page 2 of 4

papillary serous carcinoma. [REDACTED]

The remainder of this frozen section specimen is submitted entirely in cassette A1.

In addition to this large firm nodule (6.0 x 5.0 x 3.0 cm, frozen section obtained from middle of nodule), there are additional nodules which are slightly softer in consistency. Also present are some thin, fluid-filled cysts. These nodules are scattered throughout the omentum and are at the edges of the resected specimen. Serial sectioning of all nodules reveal that most nodules are of the firm-white variety with a few nodules being extremely soft and almost papillated on cut appearance. The thin, fluid-filled areas when cut reveal cystic spaces filled with some clear serous fluid as well as some papillary regions. Additional representative sections are submitted as follows:

Cassette A2 Cystic portion of tumor with cyst wall and papillary excrescences extruding into cyst wall

Cassette A3 Additional section of fibrous large nodule

Cassette A4 Representative section of soft papillary portion of tumor

Cassette A5 Additional representative section of one of the firm nodules

Part B, additionally labeled "pelvic mass left" consists of multiple fragments of extremely soft, irregularly-shaped, tan-white tissue measuring approximately 6.0 x 7.0 x 2.0 cm in aggregate. A small piece of this tissue is submitted for frozen section diagnosis.

FROZEN SECTION DIAGNOSIS #2

Left pelvic mass, biopsy: neoplasm, favor malignant, final diagnosis deferred. [REDACTED]

The remainder of the frozen section tissue is submitted entirely in cassette B1. An additional representative section is submitted in cassette B2.

Part C, additionally labeled "right ovary and tube" consists of a large mass of soft, irregularly-shaped bosselated tissue measuring 7.0 x 7.0 x 3.5 cm in greatest dimension. Protruding along one edge of this mass of tissue appears to be a fallopian tube which is slightly dilated in portions, especially more distal. The fimbriated ends of the this fallopian tube are slightly blunted. A small, white, firm structure, possibly representing an ovary is noted on the surface of this mass and measures approximately 2.0 x 1.0 x 0.8 cm. This mass is bisected to reveal an ovary which has been largely replaced by this large soft, bosselated lesion. The remaining ovarian tissue appears to be grossly unremarkable. This papillary process involves the entire ovary, however, no definite ovarian source of origin is grossly identified. The fallopian tubes are then serially sectioned to reveal grossly unremarkable fallopian tubes in the proximal portion and a dilated fallopian tube in the distal portion

[page 3 of 4]
[REDACTED]

with what appears to be tumor in the lumen. Representative sections are submitted as follows:

Cassette C1 Fallopian tube (normal and with tumor)

Cassette C2 Ovary with relation to papillary growth

Cassette C3 Additional section of grossly unremarkable
ovary adjacent to papillary growth

Part D, additionally labeled "left pelvic mass" consists of multiple fragments of soft, irregularly-shaped, tan-white papillated tissue measuring 10.0 x 5.5 x 5.0 cm in aggregate. No identifiable organ is found within this tissue mass. Portions of the mass appears to be slightly more solid while other portions are more papillary. Representative sections of the more solid portions are submitted in cassette D1 and representative sections of the more papillary area are submitted in cassette D2.

Part E, additionally labeled "pelvic tumor" consists of multiple fragments of friable, irregularly-shaped, soft tan-yellow tissue measuring 15.0 x 11.0 x 6.0 cm in aggregate. The tissue appears to consist of multiple nodules of friable solid to papillary tissue ranging in size from 0.5 x 0.3
Page 3 of 4

x 0.1 cm to 9.0 x 5.0 x 2.0 cm. These large nodules are sectioned to reveal some predominantly solid areas while other areas demonstrate a more papillary appearance. On the exterior surface of one of the nodules, there appears to be a firm white-yellow fibrous portion of unknown significant. Representative section of this firm white-yellow area next to tumor is submitted in cassette E1 and an additional representative section of tumor is submitted in cassette E2.

Part F, additionally labeled "sigmoid tumor" consists of three friable pieces of red-tan, soft, irregularly-shaped tissue measuring 2.0 x 0.8 x 2.0 cm in aggregate. One of the pieces appears to be some fibrous tissue while the other two pieces are more polypoid in appearance. The two polypoid pieces are bisected and the specimen is submitted entirely in cassette F1.

Part G, additionally labeled "uterus, cervix" consists of an uterus with attached cervix and without adnexa weighing 47 grams. The uterus measures 7.3 cm from fundus to cervix, 4.1 cm from cornu to cornu, 2.9 cm from anterior to posterior, and is oriented by the peritoneal reflexion. The serosa is smooth and is not distorted. The uterine cavity sounds to 6.3 cm. The cervix measures 2.5 cm in length and 3.0 cm in width. The external os is fish mouth-shaped and measures 1.3 cm in width. The uterus is opened along the lateral borders. The ectocervix and endocervical canal are unremarkable. The endometrium is tan, measures 0.1 cm in thickness, and contains no polyps. The myometrium measures 1.2 cm and contains no leiomyomas. On the posterior surface of the cervical uterine junction, there is a small firm nodule measuring 1.2 x 0.5 x 0.4 cm. This nodule is sectioned to reveal a firm homogenous interior. The main substance of the uterus and cervix appear to be grossly uninvolved by tumor; however, more parametrial tissue is present on the left than right. The left parametrial tissue appears to be grossly involved by tumor. Representative sections are submitted as follows:

Cassette G1 Firm nodule at external posterior cervical
uterine junction (in entirety)

Cassette G2 Anterior cervix

Cassette G3 Posterior cervix

Cassette G4 Anterior endomyometrium

Cassette G5 Posterior endomyometrium

Cassette G6 Left parametrium

Cassette G7 Right parametrium

Part H, additionally labeled "sigmoid serosa tumor" consists of multiple fragments of extremely friable, irregularly-shaped, soft, tan-white tissue measuring 10.0 x 8.0 x 2.0 cm in aggregate. The tissue is sectioned to reveal some portions of solid consistency while others are more papillary and friable. Representative sections of the more solid portions are submitted in cassette H1 and representative sections of the more papillary portions are submitted in cassette H2.

[REDACTED]

[page 4 of 4]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file fa2afa15-f130-409c-8618-effa4ba57d45 (TCGA-09-2045.6C826E9D-B1AA-4C84-B294-C8FB41818DA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).